Gene-level copy-number profile of tumor specimen TCGA-AA-3970-01A from TCGA case TCGA-AA-3970, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.0 years (23,741 days).
Specimen TCGA-AA-3970-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.2ec89cb0-69e7-4504-876b-641f5937dae8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3970-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/e1665430-f6ce-4acf-8953-f35b7b5d8d4e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,773; copy number 2: 45,037; copy number 3: 4,420; copy number 4: 1,611; copy number 5: 979.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 979 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:13,008,972–18,381,484, 80 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr20:18,420,160–18,421,454, 1 gene, copy number 5: GCNT1P1.
- chr20:30,278,906–64,313,132, 898 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,773. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
